Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3ZQ, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3ZQ-01A (Primary Tumor).

Surgical Pathology Report

DOB: _____
Physician: _____

Collected _____
Received _____

Case type: Surgical Case

DIAGNOSIS

(A) TOTAL THYROIDECTOMY:
PAPILLARY THYROID CARCINOMA, CONVENTIONAL TYPE
Location: Right lobe
Multi-focal: No
Size = 3.6 cm
Extrathyroidal extension: Absent
Lymphovascular invasion: Absent
Resection Margins: Negative
Background Thyroid: mild chronic lymphocytic thyroiditis
Lymph nodes: No tumor present in 1 lymph node

1CD-0-3
carcinoma, papillary, thyroid
8260/3

Site: thyroid, NOS C73.9

hw
6/17/12

GROSS DESCRIPTION

(A) TOTAL THYROIDECTOMY, DOMINANT NODULE ON RIGHT – an asymmetric thyroid with right lobe distended (4.0 x 3.1 x 2.0 cm), isthmus (2.0 x 1.0 x 0.3 cm) and left lobe (4.5 x 1.5 x 0.8 cm) with smooth surface overlying the entire gland.

The right lobe is replaced by a pink-tan nodule filling the lobe (3.6 x 2.8 x 2.0, with scant rim of normal parenchyma grossly identified.

The isthmus and left lobes are unremarkable without extension of the mass into this region.

SECTION CODE: A1-3, Left lobe representative superior to inferior; A4-5, isthmus; A6-A16 Right lobe from superior to inferior with mass.

CLINICAL HISTORY

Papillary thyroid carcinoma.

SNOMED CODES

T-B6000, M-80503, M-B0630

"Some tests reported here may have been developed and performance characteristics determined by approved by the U.S. Food and Drug Administration."

These tests have not been specifically cleared or

Entire report and diagnosis completed by: |

Source: NCI Genomic Data Commons file b59a1519-dd17-4068-9b87-d68ac49b31c4 (TCGA-EL-A3ZQ.1C104C06-BB8E-49C8-851E-79D0EC5C89B0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).